Somatic mutation profile of tumor specimen TCGA-2L-AAQE-01A (aliquot TCGA-2L-AAQE-01A-11D-A397-08) from TCGA case TCGA-2L-AAQE, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 56.4 years (20,618 days).
Specimen TCGA-2L-AAQE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3264787b-05bd-4a9a-8ef2-da9a93a15195.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2L-AAQE-11A (Solid Tissue Normal), aliquot TCGA-2L-AAQE-11A-11D-A39A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5124e04b-d844-4aed-85bd-0e77b7e89e22

The open-access MAF lists 38 somatic variants for this specimen: 30 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 7, 5'UTR 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.247C>T p.H83Y | Missense Mutation (SNP) | VAF 17/70 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs121913385, CM053801, CM056557, COSV58682852, COSV58685578, COSV58690009; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 80/277 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC1 | c.1655C>T p.T552I | Missense Mutation (SNP) | VAF 43/219 reads (20%) | SIFT tolerated (0.93); PolyPhen possibly damaging (0.848); catalogued as rs1473878950, COSV100579566; called by muse, mutect2, varscan2
- ABRA | c.205C>T p.P69S | Missense Mutation (SNP) | VAF 62/591 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.055); catalogued as COSV100357572, COSV61731948; called by muse, mutect2, varscan2
- ANKS1B | c.1336T>A p.F446I | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV100245607; called by muse, mutect2, varscan2
- ANO3 | c.914G>A p.R305Q | Missense Mutation (SNP) | VAF 113/441 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772297446, COSV56793363; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BCAT2 | c.712G>A p.V238M | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as rs139881168; called by muse, mutect2, varscan2
- C10orf71 | c.1885G>A p.G629R | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs377136815, COSV60509770; called by muse, mutect2, varscan2
- COL22A1 | c.1460G>A p.G487E | Missense Mutation (SNP) | VAF 51/824 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as rs267601793, COSV100278526; called by muse, mutect2
- DAND5 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 97/348 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as rs375577023; called by muse, mutect2, varscan2
- DOP1B | c.2632C>T p.R878C | Missense Mutation (SNP) | VAF 49/344 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV101215392; called by muse, mutect2, varscan2
- ELP4 | c.238G>A p.V80I | Missense Mutation (SNP) | VAF 86/338 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.049); catalogued as rs202180164, COSV63355431; called by muse, mutect2, varscan2
- FBN3 | c.6160G>A p.E2054K | Missense Mutation (SNP) | VAF 53/188 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as rs149936210; called by muse, mutect2, varscan2
- FLG | c.566A>T p.E189V | Missense Mutation (SNP) | VAF 10/218 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.716); catalogued as COSV100911592; called by muse, mutect2
- GLYATL1 | c.821G>A p.R274H (on ENST00000317391 / NM_001354699.1; = p.R305H on NM_080661.4) | Missense Mutation (SNP) | VAF 90/343 reads (26%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as rs199557152, COSV100265476, COSV55611942; called by muse, mutect2, varscan2
- IMPDH2 | c.1064G>A p.R355Q | Missense Mutation (SNP) | VAF 155/593 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.327); catalogued as COSV100455042; called by muse, mutect2, varscan2
- ITGAX | c.2869G>T p.V957F | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.919); catalogued as rs775306923, COSV99191715; called by muse, varscan2
- LTB4R | c.110G>C p.S37T | Missense Mutation (SNP) | VAF 178/661 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.021); catalogued as COSV99350721; called by muse, mutect2, varscan2
- MAGEB2 | c.856A>T p.M286L | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.449); catalogued as rs760208597, COSV100975664; called by muse, mutect2, varscan2
- MAGEE2 | c.773A>G p.H258R | Missense Mutation (SNP) | VAF 54/234 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.078); catalogued as COSV100973082; called by muse, mutect2, varscan2
- PCDHA7 | c.2068G>A p.E690K | Missense Mutation (SNP) | VAF 59/518 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.005); catalogued as COSV100970749; called by muse, mutect2, varscan2
- POU4F3 | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 56/283 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57942451; called by muse, mutect2, varscan2
- RND1 | c.367A>T p.I123F | Missense Mutation (SNP) | VAF 129/394 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.378); catalogued as rs765295653, COSV100552167; called by muse, mutect2, varscan2
- SPOCK1 | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 68/277 reads (25%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.997); catalogued as rs535025555, COSV99969058; called by muse, mutect2, varscan2
- SRRM4 | c.686T>A p.L229H | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as COSV99938535; called by muse, mutect2, varscan2
- TEX14 | c.3265G>C p.E1089Q (on ENST00000240361 / NM_001201457.2; = p.E1083Q on NM_198393.4) | Missense Mutation (SNP) | VAF 63/305 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.421); catalogued as COSV99542278; called by muse, mutect2, varscan2
- TP53 | c.112C>T p.Q38* | Nonsense Mutation (SNP) | VAF 273/783 reads (35%) | catalogued as CM107390, COSV52689258; called by muse, mutect2, varscan2
- UGT3A2 | c.811T>A p.L271M | Missense Mutation (SNP) | VAF 43/336 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99236370; called by muse, mutect2, varscan2
- ZNF780B | c.1741G>A p.G581R | Missense Mutation (SNP) | VAF 75/584 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369018278; called by muse, mutect2, varscan2
- KDM6A | c.713_731del p.S238Lfs*6 | Frame Shift Del (DEL) | VAF 36/124 reads (29%) | called by mutect2, pindel
- ANK1 | c.1618C>T p.L540= | Silent (SNP) | VAF 214/417 reads (51%) | catalogued as COSV99225301; called by muse, mutect2, varscan2
- DMKN | c.135C>T p.D45= | Silent (SNP) | VAF 69/359 reads (19%) | catalogued as rs113646456; called by muse, mutect2, varscan2
- GTF3C5 | c.216C>T p.H72= | Silent (SNP) | VAF 56/366 reads (15%) | catalogued as COSV100565406; called by muse, mutect2, varscan2
- HIF3A | c.1737C>T p.D579= (on ENST00000377670 / NM_152795.4; = p.D510= on NM_022462.4) | Silent (SNP) | VAF 39/197 reads (20%) | catalogued as rs772319491, COSV52195624; called by muse, mutect2, varscan2
- PTK6 | c.315G>A p.R105= | Silent (SNP) | VAF 17/99 reads (17%) | catalogued as rs1333559755, COSV53917741; called by muse, mutect2, varscan2
- SUPT20HL2 | c.1974G>T p.A658= | Silent (SNP) | VAF 112/239 reads (47%) | called by muse, mutect2, varscan2
- ZNF280A | c.762C>T p.D254= | Silent (SNP) | VAF 197/507 reads (39%) | catalogued as rs1346836335, COSV100131057; called by muse, mutect2, varscan2
- IFRD2 | c.-125G>A | 5'UTR (SNP) | VAF 51/202 reads (25%) | catalogued as COSV100269505; called by muse, mutect2, varscan2
